Surgical pathology report (de-identified scan), TCGA case TCGA-B9-A8YI, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-A8YI-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY

Case Number :

ICD-O-3

*Carcinoma, papillary
renal cell 8260/3
Site @ Kidney NDS C64.9
JW 4/11/14*

Diagnosis:

A: Kidney, left, partial nephrectomy

Procedure: partial nephrectomy

Laterality: left

Histologic tumor type/subtype: papillary renal cell carcinoma, type II

Sarcomatoid features: absent

Histologic grade (if applicable): Fuhrman grade 2

Tumor size (greatest dimension): 4.5 cm (per gross examination)

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: absent

Gerota's fascia: absent

Renal sinus: absent

Major veins (renal vein or segmental branches, IVC): not applicable

Ureter: not applicable

Venous (large vessel): not applicable

Lymphatic (small vessel): absent

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): negative (5 mm)

Renal capsular margin (partial nephrectomy only): negative

Paranephric adipose tissue margin (partial nephrectomy only): negative

Adrenal gland: not submitted

Lymph nodes: not submitted

Pathologic findings in non-neoplastic kidney: Focal global glomerulosclerosis and mild interstitial nephritis.

[page 2 of 2]
AJCC Staging:

pT1b

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

year-old male with a clinical diagnosis of a renal mass.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left renal mass." It holds a 91.1 gram, 7.1 x 6.0 x 5.5 cm partial nephrectomy. The capsule is yellow, smooth and inked blue. The parenchymal margin is tan/brown and inked black. Just beneath the capsule, there is a roughly 4.5 x 4.2 x 2.6 cm partially solid, partially cystic red/brown to yellow variegated mass. The mass abuts the capsule, but does not extend through it and comes to within 0.4 cm of the black inked parenchymal margin. No additional abnormalities are noted.

Block summary:

A1-A2 - mass with closest approach to blue inked parenchymal margin, perpendicular

A3-A4 - mass capsule, perpendicular

A5 - parenchyma away from mass

Tissue remains in formalin.

Tissue is submitted to Tissue Procurement.

Source: NCI Genomic Data Commons file 0f349a88-3710-4d6a-aef7-550366f2c8e2 (TCGA-B9-A8YI.4E84E1C3-DD66-476B-AA7B-E4492A1CBED5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).